Gene-level copy-number profile of specimen HCM-BROD-0231-C25-85N from HCMI case HCM-BROD-0231-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 68.9 years (25,156 days).
Specimen HCM-BROD-0231-C25-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1392baa4-0e46-4562-b37e-9f0dd994b83f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0231-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/75cad323-1ac6-4381-b5ca-d4ce501e2798

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 12,475; copy number 3: 7,257; copy number 4: 21,793; copy number 5: 16,865; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
